Somatic mutation profile of tumor specimen BA3434D (aliquot aq-BA3434D) from BEATAML1.0 case 2651, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 78.3 years (28,581 days).
Specimen BA3434D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b87cc889-8be1-4787-8193-b716976db11a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3091D (Solid Tissue Normal), aliquot aq-BA3091D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18a24806-02b0-41a8-9eea-a9be6f8b283c

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 11, Frame Shift Del 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IKZF1 | c.476A>G p.N159S | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs374333820, COSV58786758; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.183A>T p.Q61H | Missense Mutation (SNP) | VAF 97/335 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.316); catalogued as rs121913255, COSV54736320, COSV54736991, COSV54744813; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- DNMT3A | c.1930del p.A644Lfs*7 | Frame Shift Del (DEL) | VAF 96/195 reads (49%) | catalogued as COSV99265591; called by mutect2, varscan2
- NTRK3 | c.1702C>G p.L568V | Missense Mutation (SNP) | VAF 56/214 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV62312320; called by muse, mutect2, varscan2
- PMEL | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 51/186 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.04); catalogued as COSV59384936; called by muse, mutect2, varscan2
- KLHL10 | c.460C>G p.P154A | Missense Mutation (SNP) | VAF 13/377 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.542); called by muse, mutect2
- MYH1 | c.366C>G p.F122L | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- NPNT | c.1370C>A p.A457E | Missense Mutation (SNP) | VAF 62/118 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- PCNX3 | c.3973C>G p.L1325V | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- ROBO2 | c.3186G>T p.Q1062H | Missense Mutation (SNP) | VAF 57/194 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.188); called by mutect2, varscan2
- UNC80 | c.4345G>C p.A1449P | Missense Mutation (SNP) | VAF 70/259 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- UQCRFS1 | c.197C>G p.A66G | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PLXNA3 | c.1590C>T p.H530= | Silent (SNP) | VAF 36/83 reads (43%) | catalogued as rs201953943, COSV63754524; called by muse, mutect2
